Somatic mutation profile of tumor specimen TCGA-K4-A83P-01A (aliquot TCGA-K4-A83P-01A-11D-A34U-08) from TCGA case TCGA-K4-A83P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 77.9 years (28,463 days).
Specimen TCGA-K4-A83P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 702a845a-4d3c-4065-8460-4063cbe608a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A83P-10A (Blood Derived Normal), aliquot TCGA-K4-A83P-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adb46945-63d9-41a3-b412-b3616b453be4

The open-access MAF lists 245 somatic variants for this specimen: 188 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 52, Nonsense Mutation 12, Frame Shift Del 3, Splice Site 3, Splice Region 2, RNA 2, Nonstop Mutation 1, 3'UTR 1, Intron 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 7/79 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV54062992, COSV54071143; called by muse, mutect2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 35/301 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 19/167 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4129C>G p.P1377A | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); catalogued as COSV55299071; called by muse, mutect2
- ADAMTS15 | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs750323599, COSV54510032; called by mutect2, varscan2
- ANKRD52 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV57287644; called by muse, mutect2, varscan2
- AOAH | c.1491T>A p.N497K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV51751085; called by muse, mutect2, varscan2
- ARHGAP31 | c.3170T>G p.I1057S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV51799602; called by muse, mutect2
- ARID1A | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | catalogued as COSV61376568; called by muse, mutect2, varscan2
- ARL13B | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs767393160, COSV57397362, COSV57402086; called by muse, mutect2, varscan2
- ASXL3 | c.446T>A p.F149Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52480540; called by muse, mutect2
- ATE1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV56443020, COSV99816669; called by muse, mutect2
- ATP2B1 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV53805801; called by muse, mutect2, varscan2
- B3GALNT2 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV64004638; called by muse, mutect2, varscan2
- BACH2 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 31/367 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV57603269, COSV57610051; called by muse, mutect2
- BMP3 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as COSV51096071; called by muse, mutect2
- BUB1 | c.1805C>G p.S602C | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV57067443; called by muse, mutect2
- C12orf4 | c.549A>T p.K183N | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV54210190; called by muse, mutect2
- C4A | c.3373G>C p.D1125H | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113822282; called by muse, mutect2
- CABYR | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.82); catalogued as COSV100509902; called by muse, mutect2
- CACNA1S | c.647A>G p.E216G | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62944096; called by muse, mutect2
- CADPS2 | c.1702G>T p.V568L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.238); catalogued as COSV57387554; called by muse, mutect2
- CARD6 | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV54569300; called by muse, mutect2, varscan2
- CCDC191 | c.42G>C p.R14S | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55562008; called by muse, mutect2
- CLINT1 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51629306; called by muse, mutect2, varscan2
- CLIP1 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV56809083; called by muse, mutect2
- COL1A2 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51966655; called by muse, mutect2
- CRACR2A | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs758562218, COSV52918791; called by muse, mutect2, varscan2
- CSF1 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60035531; called by muse, mutect2
- CSF2RA | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1240704119, COSV62626906; called by muse, mutect2
- CSMD1 | c.10277T>A p.V3426E (on ENST00000520002; = p.V3425E on NM_033225.6) | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV59388459; called by muse, mutect2
- CTTN | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as COSV57230451, COSV57236455; called by muse, mutect2
- CYC1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV59645141; called by muse, mutect2
- CYP11B1 | c.1250T>C p.F417S | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52831582, COSV99454334; called by muse, mutect2
- DCANP1 | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.856); catalogued as COSV72345927; called by muse, mutect2, varscan2
- DHRS2 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51634460; called by muse, mutect2, varscan2
- DICER1 | c.3116C>G p.A1039G | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.91); catalogued as COSV58624062, COSV58627132, COSV58628866; called by muse, mutect2
- DNAH2 | c.3262G>A p.V1088M | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs769705508, COSV66727864; called by muse, mutect2, varscan2
- DNAH6 | c.1943A>T p.E648V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as COSV99404226; called by muse, mutect2
- DNAJC6 | c.1835A>G p.Q612R | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV54782210; called by muse, mutect2
- DOP1A | c.5506G>A p.E1836K | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV52718719; called by muse, mutect2
- DPAGT1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99597783; called by muse, mutect2
- ELAVL2 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.444); catalogued as COSV56371771; called by muse, mutect2
- EMB | c.857A>C p.Q286P | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100296561; called by muse, mutect2
- ENAM | c.2607C>G p.S869R | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV68537079; called by muse, mutect2
- EPB41L3 | c.1808A>G p.D603G | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59468750; called by muse, mutect2
- EPHA3 | c.1868T>C p.I623T | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60729001; called by muse, mutect2
- FAM47C | c.2816G>C p.G939A | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792906, COSV63724366; called by muse, mutect2, varscan2
- FARSB | c.114+2T>C p.X38_splice | Splice Site (SNP) | VAF 10/149 reads (7%) | catalogued as COSV56052804; called by muse, mutect2
- FRZB | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54556226; called by muse, mutect2
- GABRA1 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376907797, COSV104376868, COSV99195674; called by muse, mutect2
- GABRA1 | c.549A>C p.K183N | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV50120867; called by muse, mutect2
- GJA1 | c.1067T>G p.L356R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV56999750; called by muse, mutect2
- GJA8 | c.243G>C p.Q81H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53790784, COSV99569539; called by muse, mutect2
- GPR149 | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV67670374; called by muse, mutect2
- GPR85 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as COSV51785518; called by muse, mutect2
- GRIN2A | c.3059C>A p.S1020Y | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV58057795; called by muse, mutect2
- GYS2 | c.724T>C p.Y242H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV53922690, COSV53929189; called by muse, mutect2
- HELZ | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as COSV62381153; called by muse, mutect2
- HEY1 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as COSV61233746; called by muse, mutect2
- HSF5 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100050670; called by muse, mutect2, varscan2
- ICAM5 | c.1752G>C p.W584C | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55749423; called by muse, mutect2
- IDH1 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61615885, COSV61642618; called by muse, mutect2
- IFIH1 | c.2425C>T p.L809F | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55130428; called by muse, mutect2
- IFRD2 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100269222; called by muse, mutect2
- IGFN1 | c.2920G>T p.A974S (on ENST00000295591 / NM_001367841.1; = p.A3431S on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55185743; called by muse, mutect2, varscan2
- IGLV2-8 | c.156C>A p.N52K | Missense Mutation (SNP) | VAF 45/448 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); catalogued as rs763109090; called by muse, varscan2
- IGLV2-8 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as rs749756388; called by muse, varscan2
- IGSF10 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56792179; called by muse, mutect2
- IL33 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV67343360; called by muse, mutect2
- ING3 | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV59952278; called by muse, mutect2
- INTS1 | c.5776G>A p.E1926K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs746675569, COSV67179916; called by muse, mutect2, varscan2
- IPO7 | c.2530C>G p.L844V | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65687182; called by muse, mutect2
- IRAG2 | c.2980G>A p.D994N (on ENST00000636465; = p.D39N on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.81); catalogued as COSV63140995; called by muse, mutect2, varscan2
- ISM1 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99339456; called by muse, mutect2
- ITGAL | c.2460C>A p.D820E | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV63324540; called by muse, mutect2, varscan2
- ITLN1 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs746507778, COSV58277026; called by muse, mutect2
- ITLN2 | c.977G>C p.*326Sext*26 | Nonstop Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100600671; called by muse, mutect2, varscan2
- ITSN2 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.899); catalogued as COSV61954284; called by muse, mutect2
- JUN | c.792C>G p.I264M | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV64664794; called by muse, mutect2
- KAT6B | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV99767141; called by muse, mutect2
- KCNH5 | c.2399C>A p.P800Q | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); catalogued as COSV59779315; called by muse, mutect2
- KCNH8 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs199796239, COSV60474138; called by muse, mutect2, varscan2
- KCNK3 | c.282C>T p.I94= | Splice Region (SNP) | VAF 7/72 reads (10%) | catalogued as COSV57194846; called by muse, mutect2
- KIAA0319L | c.2385C>G p.I795M | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV57851084; called by muse, mutect2
- KIF4B | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV70531722; called by muse, mutect2
- KIFAP3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63037613; called by muse, mutect2
- KRT23 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as COSV52929191; called by muse, mutect2
- LMTK2 | c.3752C>T p.S1251F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV52003719; called by muse, mutect2, varscan2
- LRP4 | c.4709A>G p.Y1570C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66138893; called by muse, mutect2, varscan2
- MAP1A | c.6098T>C p.F2033S | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV55813220; called by muse, mutect2
- MAP4K5 | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV50162013, COSV50162949; called by muse, mutect2, varscan2
- MAPK8 | c.851C>G p.S284* | Nonsense Mutation (SNP) | VAF 7/155 reads (5%) | catalogued as COSV100827341; called by muse, mutect2
- MAST4 | c.5425C>G p.L1809V (on ENST00000403625 / NM_001164664.2; = p.L1620V on NM_015183.3) | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs774644266, COSV55143464; called by muse, mutect2
- METTL3 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52968357; called by muse, mutect2
- MPEG1 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57095414; called by muse, mutect2
- MPP7 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV61738527; called by muse, mutect2
- MS4A2 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV54014008; called by muse, mutect2
- MS4A2 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54014014; called by muse, mutect2
- MTMR11 | c.1663C>A p.P555T (on ENST00000439741 / NM_001145862.2; = p.P483T on NM_181873.3) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.745); catalogued as COSV54967027; called by muse, mutect2
- MYCBPAP | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100087533; called by muse, mutect2
- MYH4 | c.5547A>T p.R1849S | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55126998; called by muse, mutect2
- MYO16 | c.2251T>C p.F751L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV51819744; called by muse, mutect2, varscan2
- MYO3A | c.4039G>C p.D1347H | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as COSV56350834; called by muse, mutect2
- NAA15 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56722897; called by muse, mutect2
- NCAN | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs757967232, COSV53059658; called by muse, mutect2, varscan2
- NDUFAF7 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1271933608, COSV50019070, COSV99135788; called by muse, mutect2
- NLRP3 | c.1796C>G p.S599C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60231446; called by muse, mutect2, varscan2
- NLRP8 | c.2641G>C p.D881H | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52583435, COSV52594457; called by muse, mutect2
- NOTCH4 | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100900279, COSV66684785; called by muse, mutect2, varscan2
- OGDH | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 8/244 reads (3%) | catalogued as COSV56048712, COSV56053761, COSV99758179; called by muse, mutect2
- OR2H1 | c.548T>A p.I183N | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65811511; called by muse, mutect2
- OR2L2 | c.125T>A p.L42Q | Missense Mutation (SNP) | VAF 21/319 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV63547851, COSV63561560; called by muse, mutect2
- OR2L2 | c.753T>A p.Y251* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | catalogued as COSV100822962, COSV100823860; called by muse, mutect2, varscan2
- PABPC1 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV59408244; called by muse, mutect2, varscan2
- PCDH11Y | c.2413A>T p.N805Y (on ENST00000400457 / NM_032973.2; = p.N794Y on NM_032971.3) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53092363; called by muse, mutect2
- PCDH11Y | c.2415T>A p.N805K (on ENST00000400457 / NM_032973.2; = p.N794K on NM_032971.3) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53092382; called by muse, mutect2
- PCDHA12 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.385); catalogued as COSV56531530, COSV56548836; called by muse, mutect2
- PCDHGA8 | c.113A>T p.E38V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54039856; called by muse, mutect2
- PEG3 | c.4673A>C p.Q1558P | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55648738; called by muse, mutect2, varscan2
- PER1 | c.3662C>G p.S1221* | Nonsense Mutation (SNP) | VAF 7/109 reads (6%) | catalogued as COSV100424176; called by muse, mutect2
- PGBD2 | c.629A>G p.H210R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.579); catalogued as rs772654353, COSV61401219; called by muse, mutect2
- PHF3 | c.4549G>C p.D1517H | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV50344166; called by muse, mutect2
- PHIP | c.5234A>T p.K1745M | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV51511244; called by muse, mutect2
- PKHD1 | c.5824G>A p.D1942N | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV61895921; called by muse, mutect2
- PKHD1L1 | c.5068G>T p.G1690C | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV65754101; called by muse, mutect2
- PLCL2 | c.2600A>G p.E867G (on ENST00000615277 / NM_001144382.2; = p.E741G on NM_015184.5) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV67625607; called by muse, mutect2
- PLTP | c.721del p.L241* | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as rs1240889623; called by mutect2, pindel, varscan2
- PPP1R14C | c.465G>C p.R155S | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV63176664; called by muse, mutect2
- PROKR2 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as COSV54089490; called by muse, mutect2
- PTPRJ | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as rs899427743, COSV69249671, COSV69255232; called by muse, mutect2
- PYGO1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100114400; called by muse, mutect2
- R3HDM1 | c.1178G>T p.S393I | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51533243, COSV99925676; called by muse, mutect2
- RANBP9 | c.1411C>G p.Q471E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV50586414; called by muse, mutect2, varscan2
- RASA2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53946796; called by muse, mutect2
- RBM17 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV101159010, COSV65914284; called by muse, mutect2
- RBM6 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56488414; called by muse, mutect2, varscan2
- RGS9 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV52226775, COSV52229580; called by muse, mutect2
- SCN9A | c.5314G>C p.E1772Q (on ENST00000303354; = p.E1761Q on NM_002977.3) | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57625618; called by muse, mutect2
- SEC23IP | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV100957195, COSV64833240; called by muse, mutect2, varscan2
- SELENON | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV62526402; called by muse, mutect2
- SETBP1 | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs768081411, COSV99951645; called by muse, mutect2
- SI | c.2101A>T p.T701S | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV52302401; called by muse, mutect2
- SLC35A4 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100021021; called by muse, mutect2
- SLC4A1AP | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58136086; called by muse, mutect2
- SLCO1A2 | c.659T>A p.V220D | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56611601; called by muse, mutect2, varscan2
- SLTM | c.2920C>G p.Q974E | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1157861043, COSV65850443; called by muse, mutect2
- SMC6 | c.775C>G p.Q259E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV100704676; called by muse, mutect2
- SNTG1 | c.1414T>A p.L472I | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV52435024, COSV52474853; called by muse, mutect2
- SP1 | c.902C>G p.S301* (on ENST00000327443 / NM_138473.3; = p.S294* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | catalogued as COSV100540360, COSV59404030; called by muse, mutect2
- SPDYE1 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 21/255 reads (8%) | catalogued as COSV99323814; called by muse, mutect2
- ST6GALNAC3 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | PolyPhen benign (0.101); catalogued as COSV100081034; called by muse, mutect2
- SUPT6H | c.496A>G p.M166V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58931777; called by muse, mutect2, varscan2
- TBC1D31 | c.2171A>T p.E724V | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV99782249; called by muse, mutect2
- TIMM50 | c.111C>T p.A37= | Splice Region (SNP) | VAF 6/94 reads (6%) | catalogued as COSV58680806; called by muse, mutect2
- TMC1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs147147941, COSV52769565, COSV52780012; called by muse, mutect2, varscan2
- TRIO | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs1473175637, COSV60096811; called by muse, mutect2
- TRIOBP | c.4656G>C p.E1552D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV60384794; called by muse, mutect2
- TRMO | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64293674; called by muse, mutect2, varscan2
- TTN | c.76879G>C p.D25627H (on ENST00000591111; = p.D18203H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | PolyPhen probably damaging (0.999); catalogued as COSV100617531, COSV60368401; called by muse, mutect2
- TUBA1B | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100254022; called by muse, mutect2
- UBXN7 | c.444G>C p.L148F | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56357986; called by muse, mutect2
- USP32 | c.3250-1G>A p.X1084_splice | Splice Site (SNP) | VAF 11/115 reads (10%) | catalogued as COSV56278023; called by muse, mutect2
- UTRN | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62348882; called by muse, mutect2
- VGLL2 | c.93T>A p.Y31* | Nonsense Mutation (SNP) | VAF 13/351 reads (4%) | catalogued as COSV100409805, COSV58309990; called by muse, mutect2
- XIRP2 | c.365C>G p.S122* (on ENST00000628543; = p.S297* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | catalogued as COSV54733184, COSV99737177; called by muse, mutect2
- XPR1 | c.1495C>G p.H499D | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV62560805; called by muse, mutect2
- YWHAQ | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV53004839; called by muse, mutect2
- ZBTB11 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs751383483, COSV57247152; called by muse, mutect2, varscan2
- ZNF189 | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.409); catalogued as rs781486939, COSV52277086; called by muse, mutect2
- ZNF202 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV60248745; called by muse, mutect2
- ZNF236 | c.358-1G>C p.X120_splice | Splice Site (SNP) | VAF 22/208 reads (11%) | catalogued as COSV53498347; called by muse, mutect2
- ZNF236 | c.3314C>T p.S1105L | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99468580; called by muse, mutect2
- ZNF304 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1171419222, COSV56586620; called by muse, mutect2
- ZNF438 | c.2479G>C p.E827Q | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV59191788, COSV59194159; called by muse, mutect2
- ZNF439 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58311251; called by muse, mutect2
- ZNF44 | c.935A>G p.D312G (on ENST00000356109 / NM_001164276.2; = p.D264G on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.878); catalogued as COSV61135172, COSV61136379; called by muse, mutect2
- ZNF485 | c.1005C>G p.F335L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62424554, COSV62425497; called by muse, mutect2, varscan2
- ZNF514 | c.1196C>A p.T399N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs538392091, COSV54635441; called by muse, mutect2
- ZNF638 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV100037816; called by muse, mutect2
- ZNF662 | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV60242298, COSV60243198; called by muse, mutect2
- ZNF816-ZNF321P | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV58350072; called by muse, mutect2
- ZNRF4 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs377167081; called by muse, mutect2, varscan2
- MAP2 | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- NTNG2 | c.142del p.D48Tfs*5 | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | called by mutect2, pindel, varscan2
- TTN | c.15345_15373del p.N5116Sfs*13 (on ENST00000591111; = p.N4189Sfs*13 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- VN1R5 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.155); called by muse, mutect2
- ZFP36L1 | c.815dup p.S273Lfs*18 | Frame Shift Ins (INS) | VAF 20/142 reads (14%) | called by mutect2, pindel, varscan2
- AK9 | c.3411A>G p.G1137= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV100392930; called by muse, mutect2
- ARSI | c.1065G>T p.V355= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV60818562; called by muse, mutect2, varscan2
- CAMSAP1 | c.4485C>G p.P1495= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV56728838; called by muse, mutect2, varscan2
- CFH | c.1299G>A p.E433= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV62778903; called by muse, mutect2
- CFH | c.2073T>C p.C691= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV66414026; called by muse, mutect2
- CLCN6 | c.2487G>A p.T829= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as rs960910605, COSV100411468; called by muse, mutect2
- CLEC4F | c.1326G>A p.Q442= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV55481767; called by muse, mutect2
- CNKSR1 | c.177C>T p.L59= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV64164300; called by muse, mutect2, varscan2
- CSMD2 | c.6666C>T p.L2222= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV53966852; called by muse, mutect2
- CUL9 | c.4740C>T p.P1580= | Silent (SNP) | VAF 16/298 reads (5%) | catalogued as COSV52735228; called by muse, mutect2
- DIP2A | c.960G>A p.L320= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100594997; called by muse, mutect2
- DSCAM | c.4476G>T p.V1492= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- E4F1 | c.2133C>T p.I711= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV57041496; called by muse, mutect2, varscan2
- ERCC8 | c.942G>A p.L314= (on ENST00000265038; = p.L295= on NM_000082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/127 reads (6%) | catalogued as COSV99410106; called by muse, mutect2
- ESYT2 | c.2244A>T p.S748= (on ENST00000613624; = p.S672= on NM_020728.3) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV51756986; called by muse, mutect2
- GOLGA3 | c.1653G>A p.Q551= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV52644493; called by muse, mutect2
- HOXC13 | c.816G>A p.L272= | Silent (SNP) | VAF 13/161 reads (8%) | catalogued as COSV54500037; called by muse, mutect2
- HUWE1 | c.4548G>A p.Q1516= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV53365056; called by muse, mutect2
- LRRC74A | c.153C>T p.S51= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs554766770, COSV53609803; called by muse, mutect2, varscan2
- MAGEB3 | c.15G>A p.Q5= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1347205564, COSV64397796; called by muse, mutect2
- MRPL22 | c.441G>A p.L147= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as rs1466758197, COSV54559572; called by muse, mutect2
- MRPS12 | c.72C>G p.L24= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV55501884; called by muse, mutect2, varscan2
- MST1R | c.3243C>T p.V1081= | Silent (SNP) | VAF 19/468 reads (4%) | catalogued as COSV56574336; called by muse, mutect2
- MUC16 | c.26166A>C p.A8722= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV67496300; called by muse, mutect2
- MUC16 | c.21744G>A p.L7248= | Silent (SNP) | VAF 9/233 reads (4%) | catalogued as COSV67496308; called by muse, mutect2
- OR2J2 | c.120G>A p.L40= | Silent (SNP) | VAF 24/214 reads (11%) | catalogued as COSV65847742; called by muse, mutect2, varscan2
- PARP10 | c.168C>T p.F56= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100477576; called by muse, mutect2
- PCDH9 | c.987A>G p.T329= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as rs1166204781, COSV60593000; called by muse, mutect2
- PCDHA11 | c.1959C>T p.H653= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as rs1434880600, COSV56548820; called by muse, mutect2
- PCK1 | c.1593A>G p.G531= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV60131397; called by muse, mutect2, varscan2
- PCNX4 | c.765G>A p.L255= (on ENST00000406854 / NM_001330177.2; = p.L21= on NM_022495.5) | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV58308386; called by muse, mutect2, varscan2
- PM20D1 | c.1338C>T p.G446= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV65649744; called by muse, mutect2
- PSG4 | c.157C>T p.L53= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV54932404, COSV54941410; called by muse, mutect2
- PSMB10 | c.228C>T p.I76= | Silent (SNP) | VAF 15/185 reads (8%) | catalogued as rs1298241601, COSV50452394; called by muse, mutect2
- RAPGEF1 | c.1566C>G p.V522= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV64702532; called by muse, mutect2, varscan2
- RDH10 | c.597G>A p.L199= | Silent (SNP) | VAF 10/230 reads (4%) | catalogued as COSV53584576; called by muse, mutect2
- SLC19A2 | c.1314C>T p.L438= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs149313767; called by muse, mutect2, varscan2
- SPECC1 | c.2991C>T p.F997= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV54966693, COSV99821349; called by muse, mutect2, varscan2
- SYNE1 | c.20472A>G p.Q6824= (on ENST00000367255 / NM_182961.4; = p.Q6753= on NM_033071.3) | Silent (SNP) | VAF 11/208 reads (5%) | catalogued as COSV55112183; called by muse, mutect2
- TAB1 | c.366C>T p.D122= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs754564216, COSV53372083, COSV53373278; called by muse, mutect2, varscan2
- TAS2R50 | c.411G>A p.L137= | Silent (SNP) | VAF 27/310 reads (9%) | catalogued as COSV67854827, COSV67862870; called by muse, mutect2
- TDRD1 | c.1506C>T p.H502= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as rs1324414131, COSV52596557; called by muse, mutect2, varscan2
- TMEM205 | c.30G>C p.L10= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100712258; called by muse, mutect2
- TNPO3 | c.1905G>A p.Q635= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV55287306; called by muse, mutect2
- TP53BP1 | c.2586A>G p.S862= | Silent (SNP) | VAF 8/207 reads (4%) | catalogued as rs1195856009, COSV55510090; called by muse, mutect2
- TTN | c.64413C>T p.F21471= (on ENST00000591111; = p.F14047= on NM_003319.4) | Silent (SNP) | VAF 17/323 reads (5%) | catalogued as COSV60368436; called by muse, mutect2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- WDR81 | c.4197G>A p.V1399= (on ENST00000409644 / NM_001163809.2; = p.V348= on NM_152348.4) | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV58488612; called by muse, mutect2
- WWC3 | c.2632C>T p.L878= | Silent (SNP) | VAF 14/153 reads (9%) | catalogued as COSV66503131; called by muse, mutect2, varscan2
- ZNF529 | c.1641G>A p.G547= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV61902184; called by muse, mutect2
- ZNF556 | c.588T>G p.T196= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as COSV56914445; called by muse, mutect2
- ZNF628 | c.1620C>T p.C540= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs761089331, COSV52698493; called by muse, mutect2, varscan2
- DIPK1B | chr9:136726153 G>A | 3'Flank (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- GGNBP1 | n.846+826T>C | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- LEKR1 | c.*1057A>T | 3'UTR (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100738438; called by muse, mutect2
- SLC22A20P | n.1059A>G | RNA (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SNORD116-28 | n.85G>A | RNA (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
